Somatic mutation profile of tumor specimen TARGET-15-SJMPAL043512-09A (aliquot TARGET-15-SJMPAL043512-09A-01D) from TARGET case TARGET-15-SJMPAL043512, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.5 years (5,664 days).
Specimen TARGET-15-SJMPAL043512-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8525ed57-3cc5-4867-9a5f-6071fa6d397b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL043512-15A (Fibroblasts from Bone Marrow Normal), aliquot TARGET-15-SJMPAL043512-15A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f1181d4e-7eb4-46b4-adbe-fd87619027d4

The open-access MAF lists 18 somatic variants for this specimen: 14 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Intron 2, Nonsense Mutation 2, Silent 2, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ECHDC1 | c.55G>T p.G19* (on ENST00000531967 / NM_001139510.1; = p.G13* on NM_018479.3) | Nonsense Mutation (SNP) | VAF 6/56 reads (11%) | catalogued as rs1192400136; called by muse, mutect2, varscan2
- GASK1A | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as rs768249342; called by mutect2, varscan2
- LILRA2 | c.1040G>T p.R347L | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as COSV52193551; called by muse, varscan2
- WDR17 | c.3580C>T p.R1194C | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs145946017; called by muse, mutect2, varscan2
- DMRT1 | c.1073C>A p.S358* | Nonsense Mutation (SNP) | VAF 4/33 reads (12%) | called by muse, mutect2, varscan2
- EIF2B5 | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); called by mutect2, varscan2
- EPB41L2 | c.1672G>T p.V558F | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.157); called by mutect2, varscan2
- FLII | c.2816+1G>T p.X939_splice | Splice Site (SNP) | VAF 3/13 reads (23%) | called by muse, varscan2
- FMNL2 | c.3197C>A p.A1066D | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.346); called by muse, mutect2
- L3MBTL1 | c.1599+7C>A | Splice Region (SNP) | VAF 3/28 reads (11%) | called by mutect2, varscan2
- METTL8 | c.32G>T p.C11F | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.047); called by muse, varscan2
- MROH9 | c.1681C>A p.L561I | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.027); called by muse, mutect2
- SOX13 | c.1359C>A p.S453R | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- XIRP2 | c.6365C>A p.P2122Q (on ENST00000628543; = p.P2297Q on NM_152381.6) | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- CCDC168 | c.17088G>T p.A5696= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as COSV59423467; called by muse, mutect2, varscan2
- DOP1B | c.6840C>A p.I2280= | Silent (SNP) | VAF 4/44 reads (9%) | called by muse, varscan2
- ABHD16A | c.1251-16G>T | Intron (SNP) | VAF 4/23 reads (17%) | catalogued as rs375091201; called by mutect2, varscan2
- PCSK6 | c.1858+1160G>T | Intron (SNP) | VAF 4/42 reads (10%) | catalogued as COSV100084021; called by muse, mutect2, varscan2
